Somatic mutation profile of tumor specimen TCGA-60-2722-01A (aliquot TCGA-60-2722-01A-01D-1522-08) from TCGA case TCGA-60-2722, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 66.4 years (24,267 days).
Specimen TCGA-60-2722-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 908490c1-c9a7-4467-a06f-c17e275cef24.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-60-2722-11A (Solid Tissue Normal), aliquot TCGA-60-2722-11A-01D-1522-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/513f45a5-a492-4fbd-b687-983b50d17f2c

The open-access MAF lists 339 somatic variants for this specimen: 267 protein-altering or splice-affecting, 66 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 223, Silent 66, Nonsense Mutation 21, Frame Shift Del 8, Splice Site 7, Splice Region 3, Intron 2, Translation Start Site 2, RNA 2, In Frame Del 1, 5'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1513C>G p.R505G (on ENST00000281708 / NM_001349798.2; = p.R425G on NM_018315.5) | Missense Mutation (SNP) | VAF 90/115 reads (78%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs149680468, COSV55890969, COSV55891274, COSV55898451; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KEAP1 | c.1438G>T p.G480W | Missense Mutation (SNP) | VAF 36/72 reads (50%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50260583; called by muse, varscan2
- TP53 | c.536A>G p.H179R | Missense Mutation (SNP) | VAF 41/52 reads (79%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1057519991, COSV52661025, COSV52661712, COSV52690692, COSV52937418; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA2 | c.2284G>C p.E762Q (on ENST00000614293; = p.E732Q on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/44 reads (91%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV55797786, COSV55799428; called by muse, varscan2
- ACAN | c.2308G>A p.E770K | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.691); catalogued as COSV61356492; called by muse, mutect2, varscan2
- ACIN1 | c.748G>T p.E250* | Nonsense Mutation (SNP) | VAF 283/719 reads (39%) | catalogued as COSV52973529; called by muse, mutect2, varscan2
- ADAM32 | c.594G>A p.L198= | Splice Region (SNP) | VAF 6/34 reads (18%) | catalogued as rs769256281, COSV101165394, COSV65947287; called by muse, mutect2, varscan2
- ADAMTS3 | c.619G>C p.E207Q | Missense Mutation (SNP) | VAF 82/473 reads (17%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as COSV54385585; called by muse, mutect2, varscan2
- ADAR | c.490A>T p.K164* | Nonsense Mutation (SNP) | VAF 370/844 reads (44%) | catalogued as COSV52712412; called by muse, mutect2, varscan2
- ADAR | c.308G>A p.G103E | Missense Mutation (SNP) | VAF 120/279 reads (43%) | SIFT tolerated (1); PolyPhen possibly damaging (0.601); catalogued as COSV52712430; called by muse, mutect2, varscan2
- ADGRL4 | c.337G>T p.A113S | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.007); catalogued as COSV66059509, COSV66059584; called by muse, mutect2, varscan2
- ADNP2 | c.104T>G p.L35R | Missense Mutation (SNP) | VAF 34/75 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as COSV51536316; called by muse, mutect2, varscan2
- ANK3 | c.8757G>T p.M2919I | Missense Mutation (SNP) | VAF 47/104 reads (45%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.007); catalogued as COSV55045171; called by muse, mutect2, varscan2
- AP2B1 | c.545C>T p.A182V | Missense Mutation (SNP) | VAF 127/266 reads (48%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.943); catalogued as rs763030515, COSV51997193; called by muse, mutect2, varscan2
- APOBR | c.947G>C p.G316A | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.021); catalogued as COSV60488819; called by muse, varscan2
- ARHGAP11A | c.2750C>T p.S917L | Missense Mutation (SNP) | VAF 84/198 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.251); catalogued as COSV55705267; called by muse, mutect2, varscan2
- ARHGAP12 | c.1633-2A>T p.X545_splice | Splice Site (SNP) | VAF 24/100 reads (24%) | catalogued as COSV60961486; called by muse, mutect2
- ARHGAP33 | c.1945C>T p.L649= | Splice Region (SNP) | VAF 5/32 reads (16%) | catalogued as COSV50119536; called by muse, mutect2
- ARHGEF15 | c.135A>T p.E45D | Missense Mutation (SNP) | VAF 88/104 reads (85%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as COSV62724395; called by muse, mutect2, varscan2
- ASB9 | c.559C>G p.L187V | Missense Mutation (SNP) | VAF 100/124 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66851303; called by muse, mutect2, varscan2
- ATAD3A | c.1192A>T p.M398L | Missense Mutation (SNP) | VAF 72/137 reads (53%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as COSV59231855; called by muse, mutect2, varscan2
- ATF4 | c.429T>A p.H143Q | Missense Mutation (SNP) | VAF 288/529 reads (54%) | SIFT tolerated (0.47); PolyPhen benign (0.005); catalogued as COSV57477642; called by muse, mutect2, varscan2
- ATG10 | c.560A>G p.N187S | Missense Mutation (SNP) | VAF 59/127 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.368); catalogued as rs1358378459, COSV56422766; called by muse, mutect2, varscan2
- ATP6V1B1 | c.785+1G>T p.X262_splice | Splice Site (SNP) | VAF 93/201 reads (46%) | catalogued as CS991327, COSV52268252, COSV99314101; called by muse, mutect2, varscan2
- ATXN3 | c.388-1G>A p.X130_splice | Splice Site (SNP) | VAF 149/395 reads (38%) | catalogued as COSV61493760; called by muse, mutect2, varscan2
- BAIAP2L2 | c.234G>A p.M78I | Missense Mutation (SNP) | VAF 59/185 reads (32%) | SIFT tolerated (0.28); PolyPhen benign (0.16); catalogued as COSV59268061; called by muse, mutect2, varscan2
- BBS9 | c.190C>G p.Q64E | Missense Mutation (SNP) | VAF 69/169 reads (41%) | SIFT tolerated (0.16); PolyPhen benign (0.026); catalogued as rs769256027, CM111654, COSV54157315; called by muse, mutect2, varscan2
- BEST3 | c.1735G>A p.E579K | Missense Mutation (SNP) | VAF 56/89 reads (63%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.036); catalogued as rs867886404, COSV58298930; called by muse, mutect2, varscan2
- BNIP1 | c.271A>C p.N91H | Missense Mutation (SNP) | VAF 36/48 reads (75%) | SIFT deleterious (0.02); PolyPhen benign (0.258); catalogued as COSV51570004; called by muse, mutect2, varscan2
- BSN | c.4390C>T p.P1464S | Missense Mutation (SNP) | VAF 97/119 reads (82%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as COSV56513275, COSV56516741; called by muse, mutect2, varscan2
- C1QA | c.682C>T p.Q228* | Nonsense Mutation (SNP) | VAF 33/101 reads (33%) | catalogued as COSV101009437, COSV65889265; called by muse, mutect2, varscan2
- C6 | c.2664C>A p.C888* | Nonsense Mutation (SNP) | VAF 37/111 reads (33%) | catalogued as COSV54705373; called by muse, mutect2, varscan2
- CAMK1G | c.1069G>A p.E357K | Missense Mutation (SNP) | VAF 82/204 reads (40%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs760816448, COSV50520281; called by muse, mutect2, varscan2
- CARMIL1 | c.694A>G p.T232A | Missense Mutation (SNP) | VAF 119/135 reads (88%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV61513944; called by muse, mutect2, varscan2
- CAVIN4 | c.255C>G p.I85M | Missense Mutation (SNP) | VAF 246/286 reads (86%) | SIFT deleterious (0); PolyPhen benign (0.075); catalogued as COSV100293073, COSV56866583; called by muse, mutect2, varscan2
- CCDC102B | c.838G>T p.A280S | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT tolerated (0.82); PolyPhen benign (0.01); catalogued as COSV60134990; called by muse, mutect2, varscan2
- CCDC63 | c.1365C>A p.N455K | Missense Mutation (SNP) | VAF 31/127 reads (24%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.915); catalogued as COSV57526959; called by muse, mutect2, varscan2
- CCSER1 | c.583G>T p.V195F | Missense Mutation (SNP) | VAF 77/147 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.387); catalogued as COSV61409374; called by muse, mutect2, varscan2
- CD22 | c.2425A>C p.N809H | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV50049702; called by muse, mutect2, varscan2
- CDH10 | c.751G>C p.G251R | Missense Mutation (SNP) | VAF 42/124 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52570779, COSV52574921; called by muse, mutect2, varscan2
- CEP170 | c.1877G>T p.R626I | Missense Mutation (SNP) | VAF 50/56 reads (89%) | SIFT deleterious (0.01); PolyPhen benign (0.379); catalogued as COSV60506305, COSV60510655; called by muse, mutect2, varscan2
- CERK | c.424G>T p.G142* | Nonsense Mutation (SNP) | VAF 59/122 reads (48%) | catalogued as COSV53450148; called by muse, mutect2, varscan2
- CFAP70 | c.1755C>A p.Y585* | Nonsense Mutation (SNP) | VAF 33/115 reads (29%) | catalogued as COSV60281114; called by muse, mutect2, varscan2
- CFH | c.1430G>A p.C477Y | Missense Mutation (SNP) | VAF 23/115 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66405949; called by muse, mutect2, varscan2
- CHD9 | c.4688G>T p.G1563V | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54607871; called by muse, mutect2, varscan2
- CHRD | c.2551C>T p.P851S | Missense Mutation (SNP) | VAF 15/100 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52605649; called by muse, mutect2, varscan2
- CNGB3 | c.64C>A p.Q22K | Missense Mutation (SNP) | VAF 125/200 reads (63%) | SIFT tolerated (0.47); PolyPhen benign (0.026); catalogued as COSV60685043; called by muse, mutect2, varscan2
- CNOT1 | c.3392C>T p.S1131L | Missense Mutation (SNP) | VAF 132/302 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.324); catalogued as COSV55313247; called by muse, mutect2, varscan2
- CNTNAP5 | c.3628G>C p.V1210L | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.49); PolyPhen benign (0.058); catalogued as COSV70473984; called by muse, mutect2
- COL11A1 | c.3833G>C p.R1278T | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.977); catalogued as rs1484726432, COSV62173704, COSV62182589; called by muse, mutect2, varscan2
- COL22A1 | c.2152C>A p.P718T | Missense Mutation (SNP) | VAF 157/237 reads (66%) | SIFT deleterious (0.03); PolyPhen benign (0.175); catalogued as COSV57324289; called by muse, mutect2, varscan2
- COL24A1 | c.3574T>A p.Y1192N | Missense Mutation (SNP) | VAF 29/58 reads (50%) | SIFT tolerated (0.23); PolyPhen benign (0.41); catalogued as COSV65302310; called by muse, mutect2, varscan2
- COL4A4 | c.3091C>A p.P1031T | Missense Mutation (SNP) | VAF 118/211 reads (56%) | SIFT deleterious (0.04); PolyPhen benign (0.129); catalogued as COSV61629739; called by muse, mutect2, varscan2
- COL4A4 | c.734C>T p.P245L | Missense Mutation (SNP) | VAF 62/207 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs770011392, COSV61629745; called by muse, mutect2, varscan2
- COL6A3 | c.7832C>A p.A2611E | Missense Mutation (SNP) | VAF 142/237 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV55080355, COSV55089770, COSV55094724; called by muse, mutect2, varscan2
- COL9A1 | c.1370G>C p.G457A | Missense Mutation (SNP) | VAF 37/45 reads (82%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100295485, COSV57878956; called by muse, mutect2, varscan2
- CPS1 | c.562C>A p.Q188K | Missense Mutation (SNP) | VAF 81/146 reads (55%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV51802685; called by muse, mutect2, varscan2
- CPS1 | c.2792T>G p.L931R | Missense Mutation (SNP) | VAF 62/128 reads (48%) | SIFT tolerated (0.22); PolyPhen benign (0.105); catalogued as COSV51802695; called by muse, mutect2, varscan2
- CPXCR1 | c.704C>A p.S235Y | Missense Mutation (SNP) | VAF 17/21 reads (81%) | SIFT deleterious (0); PolyPhen benign (0.362); catalogued as COSV52161128; called by muse, mutect2, varscan2
- CRYBG2 | c.703G>T p.V235L | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.006); catalogued as rs566879984, COSV57485241; called by muse, mutect2, varscan2
- CSMD2 | c.7544G>A p.G2515D | Missense Mutation (SNP) | VAF 36/148 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53882310; called by muse, mutect2, varscan2
- CUBN | c.6487T>A p.S2163T | Missense Mutation (SNP) | VAF 36/76 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.959); catalogued as COSV64708376; called by muse, mutect2, varscan2
- DAGLB | c.37A>G p.I13V | Missense Mutation (SNP) | VAF 25/42 reads (60%) | SIFT tolerated (0.22); PolyPhen benign (0.023); catalogued as COSV51702351; called by muse, mutect2, varscan2
- DCAF12L2 | c.1342G>C p.G448R | Missense Mutation (SNP) | VAF 52/76 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1208978421, COSV63580369; called by mutect2, varscan2
- DDB2 | c.1024-1G>A p.X342_splice | Splice Site (SNP) | VAF 73/95 reads (77%) | catalogued as COSV57037179; called by muse, mutect2, varscan2
- DEFA4 | c.223A>C p.T75P | Missense Mutation (SNP) | VAF 83/125 reads (66%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.529); catalogued as COSV52404458; called by muse, mutect2, varscan2
- DESI1 | c.130C>T p.H44Y | Missense Mutation (SNP) | VAF 53/92 reads (58%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV54354030; called by muse, mutect2, varscan2
- DHTKD1 | c.169G>T p.A57S | Missense Mutation (SNP) | VAF 147/268 reads (55%) | SIFT tolerated (0.4); PolyPhen benign (0.028); catalogued as COSV53801828; called by muse, mutect2, varscan2
- DMD | c.5623A>C p.I1875L | Missense Mutation (SNP) | VAF 83/95 reads (87%) | SIFT tolerated (0.29); PolyPhen benign (0.043); catalogued as COSV63736054; called by muse, mutect2, varscan2
- DNAH10 | c.10076C>A p.A3359D (on ENST00000409039; = p.A3298D on NM_207437.3) | Missense Mutation (SNP) | VAF 15/22 reads (68%) | SIFT tolerated (0.42); PolyPhen benign (0.007); catalogued as rs1428851490, COSV68988306; called by muse, mutect2, varscan2
- DNAH11 | c.6110T>A p.V2037E | Missense Mutation (SNP) | VAF 43/91 reads (47%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.549); catalogued as COSV60941189; called by muse, mutect2, varscan2
- DPYD | c.732G>T p.E244D | Missense Mutation (SNP) | VAF 53/105 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.515); catalogued as COSV64591434; called by muse, varscan2
- DUXA | c.313C>T p.R105C | Missense Mutation (SNP) | VAF 55/142 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.082); catalogued as rs145101590; called by muse, mutect2, varscan2
- EIF4ENIF1 | c.2623T>A p.Y875N | Missense Mutation (SNP) | VAF 60/166 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57514606; called by muse, mutect2, varscan2
- EIF5A2 | c.203A>C p.K68T | Missense Mutation (SNP) | VAF 63/349 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.958); catalogued as COSV55542452; called by muse, mutect2, varscan2
- FAM135B | c.2914G>T p.V972L | Missense Mutation (SNP) | VAF 35/180 reads (19%) | SIFT tolerated, low confidence (0.79); PolyPhen benign (0); catalogued as COSV52706722; called by muse, mutect2, varscan2
- FAM135B | c.1942C>A p.L648M | Missense Mutation (SNP) | VAF 121/199 reads (61%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.641); catalogued as COSV52706750; called by muse, mutect2, varscan2
- FAM216B | c.61C>T p.R21* | Nonsense Mutation (SNP) | VAF 30/80 reads (38%) | catalogued as rs1853636; called by muse, mutect2, varscan2
- FAM83E | c.826G>A p.A276T | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT tolerated (0.29); PolyPhen benign (0.141); catalogued as rs756248260, COSV52374594; called by muse, mutect2, varscan2
- FANCA | c.2201C>T p.S734F | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV66880347; called by muse, mutect2, varscan2
- FBXO30 | c.125A>T p.H42L | Missense Mutation (SNP) | VAF 117/149 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52790262; called by muse, mutect2, varscan2
- FBXO33 | c.451G>C p.G151R | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.379); catalogued as rs775184549, COSV53233332, COSV53235270; called by muse, mutect2, varscan2
- FCRL1 | c.523G>T p.E175* | Nonsense Mutation (SNP) | VAF 207/410 reads (50%) | catalogued as COSV63823939, COSV63825299; called by muse, mutect2, varscan2
- FER1L6 | c.562G>A p.D188N | Missense Mutation (SNP) | VAF 43/169 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.06); catalogued as COSV67548253, COSV67552175; called by muse, mutect2, varscan2
- FLNC | c.3932C>T p.T1311I | Missense Mutation (SNP) | VAF 37/76 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.768); catalogued as rs1183933254, COSV57950874; called by muse, mutect2, varscan2
- FRAS1 | c.3451C>A p.L1151I | Missense Mutation (SNP) | VAF 35/225 reads (16%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as COSV53591230; called by muse, mutect2, varscan2
- FRMPD2 | c.2393A>G p.Q798R | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.021); catalogued as rs376247926; called by muse, mutect2, varscan2
- GABRA1 | c.825C>A p.N275K | Missense Mutation (SNP) | VAF 59/86 reads (69%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.953); catalogued as COSV50099010; called by muse, mutect2, varscan2
- GCFC2 | c.968A>G p.Y323C | Missense Mutation (SNP) | VAF 116/275 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV58079654; called by muse, mutect2, varscan2
- GIN1 | c.637C>T p.Q213* | Nonsense Mutation (SNP) | VAF 8/40 reads (20%) | catalogued as COSV67536026; called by muse, mutect2, varscan2
- GOLGB1 | c.1804G>T p.E602* | Nonsense Mutation (SNP) | VAF 88/270 reads (33%) | catalogued as COSV61462021; called by muse, mutect2, varscan2
- GOLGB1 | c.1803G>C p.M601I | Missense Mutation (SNP) | VAF 89/272 reads (33%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV61462026; called by muse, mutect2, varscan2
- GPM6A | c.809C>A p.S270Y | Missense Mutation (SNP) | VAF 74/101 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV54533147; called by muse, mutect2, varscan2
- GPR137C | c.539T>C p.V180A | Missense Mutation (SNP) | VAF 119/273 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.51); catalogued as COSV58704019; called by muse, mutect2, varscan2
- GPR158 | c.2230C>T p.R744W | Missense Mutation (SNP) | VAF 54/206 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); catalogued as rs1157039977, COSV66265734; called by muse, mutect2, varscan2
- GRID1 | c.2426G>T p.G809V | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60014983, COSV60019952; called by muse, mutect2, varscan2
- GRID1 | c.2425G>T p.G809C | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV60014928; called by muse, mutect2, varscan2
- GSR | c.1195G>C p.E399Q | Missense Mutation (SNP) | VAF 140/224 reads (63%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.531); catalogued as COSV55319424, COSV55323737; called by muse, mutect2, varscan2
- GYS2 | c.2000G>A p.R667K | Missense Mutation (SNP) | VAF 101/161 reads (63%) | SIFT tolerated (0.49); PolyPhen benign (0.079); catalogued as COSV53920725; called by muse, mutect2
- HAGHL | c.767C>A p.A256D (on ENST00000341413; = p.R218= on NM_032304.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); catalogued as COSV52400860; called by muse, mutect2, varscan2
- HAPLN1 | c.873G>T p.Q291H | Missense Mutation (SNP) | VAF 97/357 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.174); catalogued as COSV57145547; called by muse, mutect2, varscan2
- HAUS4 | c.395A>G p.Q132R | Missense Mutation (SNP) | VAF 47/102 reads (46%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as rs761536848, COSV52826748; called by muse, mutect2, varscan2
- HECTD4 | c.10672G>A p.E3558K | Missense Mutation (SNP) | VAF 27/104 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.209); catalogued as COSV66386971; called by muse, varscan2
- HECW1 | c.3201C>G p.H1067Q | Missense Mutation (SNP) | VAF 141/345 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.886); catalogued as COSV67822484; called by muse, mutect2, varscan2
- HIF3A | c.1742A>T p.D581V (on ENST00000377670 / NM_152795.4; = p.D512V on NM_022462.4) | Missense Mutation (SNP) | VAF 38/113 reads (34%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.017); catalogued as COSV52195932; called by muse, mutect2, varscan2
- HNRNPCL1 | c.446C>G p.S149* | Nonsense Mutation (SNP) | VAF 75/280 reads (27%) | catalogued as COSV58610048, COSV58611487; called by muse, mutect2, varscan2
- HOXD1 | c.648G>C p.K216N | Missense Mutation (SNP) | VAF 23/43 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100514124, COSV58923106; called by muse, mutect2, varscan2
- HPS3 | c.2773C>G p.H925D | Missense Mutation (SNP) | VAF 35/211 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.736); catalogued as COSV56052807; called by muse, mutect2, varscan2
- HSPA13 | c.1219G>A p.G407S | Missense Mutation (SNP) | VAF 66/210 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV53464617; called by muse, mutect2, varscan2
- IBTK | c.3025+1G>T p.X1009_splice | Splice Site (SNP) | VAF 118/190 reads (62%) | catalogued as COSV60390999; called by muse, mutect2, varscan2
- IFT80 | c.932C>G p.T311R | Missense Mutation (SNP) | VAF 65/425 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.855); catalogued as COSV58445563; called by muse, mutect2, varscan2
- IL3 | c.28C>T p.L10F | Missense Mutation (SNP) | VAF 53/68 reads (78%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.818); catalogued as COSV57308434; called by muse, mutect2, varscan2
- IL37 | c.443A>G p.E148G | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.266); catalogued as COSV54490047; called by muse, mutect2, varscan2
- INPP5A | c.769G>T p.A257S | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated (0.76); PolyPhen benign (0.038); catalogued as COSV61246714; called by muse, mutect2, varscan2
- JMJD1C | c.6882A>T p.E2294D | Missense Mutation (SNP) | VAF 38/132 reads (29%) | SIFT tolerated (0.56); PolyPhen benign (0.039); catalogued as COSV59512938; called by muse, mutect2, varscan2
- JPH1 | c.920A>G p.E307G | Missense Mutation (SNP) | VAF 208/327 reads (64%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV60608776; called by muse, varscan2
- KALRN | c.7313T>C p.V2438A (on ENST00000360013 / NM_001024660.4; = p.V741A on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 60/132 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); catalogued as COSV52250206; called by muse, mutect2, varscan2
- KANSL1 | c.3194G>T p.R1065L (on ENST00000574590 / NM_001193465.2; = p.R1066L on NM_015443.4) | Missense Mutation (SNP) | VAF 46/52 reads (88%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV52237183; called by muse, mutect2, varscan2
- KCND2 | c.1685G>C p.R562T | Missense Mutation (SNP) | VAF 42/108 reads (39%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.062); catalogued as rs1249044956, COSV58570086; called by muse, mutect2, varscan2
- KCNK3 | c.419T>G p.L140R | Missense Mutation (SNP) | VAF 116/136 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV57191566; called by muse, mutect2, varscan2
- KDM5A | c.2155C>T p.R719C | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs1362895739, CM118340, COSV66991075; called by mutect2, varscan2
- KIAA0513 | c.268G>T p.E90* | Nonsense Mutation (SNP) | VAF 28/88 reads (32%) | catalogued as COSV50740634; called by muse, mutect2, varscan2
- KIF14 | c.461A>G p.N154S | Missense Mutation (SNP) | VAF 93/205 reads (45%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as COSV66259907; called by muse, mutect2, varscan2
- KNG1 | c.904G>T p.D302Y | Missense Mutation (SNP) | VAF 117/766 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV53976122; called by muse, mutect2, varscan2
- KPNA4 | c.248A>G p.D83G | Missense Mutation (SNP) | VAF 92/122 reads (75%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV62074748; called by muse, mutect2, varscan2
- LAMA1 | c.1681C>A p.Q561K | Missense Mutation (SNP) | VAF 60/158 reads (38%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV67532478; called by muse, varscan2
- LAMA1 | c.1680G>A p.M560I | Missense Mutation (SNP) | VAF 57/158 reads (36%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as COSV67532481; called by muse, varscan2
- LAMP5 | c.700G>C p.E234Q | Missense Mutation (SNP) | VAF 49/147 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1179915173, COSV55715132; called by muse, mutect2, varscan2
- LCT | c.3466C>A p.H1156N | Missense Mutation (SNP) | VAF 78/165 reads (47%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); catalogued as COSV51544493; called by muse, mutect2, varscan2
- LHCGR | c.1988G>C p.C663S | Missense Mutation (SNP) | VAF 66/530 reads (12%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as COSV54292909; called by muse, mutect2, varscan2
- LMBRD2 | c.892A>G p.S298G | Missense Mutation (SNP) | VAF 33/88 reads (38%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs756041545, COSV56948752; called by muse, mutect2, varscan2
- LPIN2 | c.1144G>T p.V382L | Missense Mutation (SNP) | VAF 63/129 reads (49%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as COSV55237405; called by muse, mutect2, varscan2
- LRPPRC | c.1625G>T p.S542I | Missense Mutation (SNP) | VAF 107/236 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.035); catalogued as COSV53234427; called by muse, mutect2, varscan2
- LTBP2 | c.629G>T p.R210L | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100000243, COSV56205118; called by muse, mutect2, varscan2
- LTV1 | c.820G>A p.E274K | Missense Mutation (SNP) | VAF 118/164 reads (72%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV52785521; called by muse, mutect2, varscan2
- LZTS1 | c.537G>C p.M179I | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.292); catalogued as COSV56115849; called by muse, mutect2
- MAP2K6 | c.89C>A p.P30H | Missense Mutation (SNP) | VAF 120/136 reads (88%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV63005129; called by muse, mutect2
- MAPKAPK2 | c.506G>T p.S169I | Missense Mutation (SNP) | VAF 272/330 reads (82%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.484); catalogued as COSV54314435; called by muse, mutect2, varscan2
- MARCO | c.570C>T p.G190= | Splice Region (SNP) | VAF 37/68 reads (54%) | catalogued as rs1441441936, COSV59051976; called by muse, mutect2, varscan2
- MBTPS1 | c.1804A>C p.T602P | Missense Mutation (SNP) | VAF 144/364 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0.034); catalogued as COSV58569456; called by muse, mutect2, varscan2
- MCTP1 | c.1860C>A p.H620Q | Missense Mutation (SNP) | VAF 70/127 reads (55%) | SIFT tolerated (0.42); PolyPhen benign (0.007); catalogued as rs1346692237, COSV56504910; called by muse, mutect2, varscan2
- MED24 | c.814C>T p.R272C | Missense Mutation (SNP) | VAF 14/220 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.019); catalogued as rs779448481, COSV62417162; called by muse, mutect2
- MINAR1 | c.1301G>T p.G434V | Missense Mutation (SNP) | VAF 57/117 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV59580970; called by muse, mutect2, varscan2
- MRPL51 | c.382C>T p.R128* | Nonsense Mutation (SNP) | VAF 65/295 reads (22%) | catalogued as rs758770414, COSV57519447; called by muse, mutect2, varscan2
- MSR1 | c.215C>A p.A72E | Missense Mutation (SNP) | VAF 80/126 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); catalogued as COSV50506996; called by muse, varscan2
- MUC16 | c.29285T>A p.L9762H | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.85); catalogued as COSV67446601; called by muse, mutect2, varscan2
- MUC16 | c.11560G>A p.G3854R | Missense Mutation (SNP) | VAF 70/145 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.087); catalogued as COSV67446605; called by muse, mutect2, varscan2
- MYBPC1 | c.2506C>G p.P836A (on ENST00000550270 / NM_206820.2; = p.P843A on NM_002465.4) | Missense Mutation (SNP) | VAF 45/247 reads (18%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV62251175; called by muse, mutect2, varscan2
- MYH11 | c.5786+2T>C p.X1929_splice | Splice Site (SNP) | VAF 64/380 reads (17%) | catalogued as rs112087760, COSV55572971; called by mutect2, varscan2
- NCKAP1 | c.1910T>C p.I637T | Missense Mutation (SNP) | VAF 87/161 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.268); catalogued as COSV62939872; called by muse, mutect2, varscan2
- NDN | c.551G>A p.R184H | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT tolerated (0.2); PolyPhen benign (0.015); catalogued as rs765248776, COSV59358232; called by muse, mutect2, varscan2
- NELL2 | c.1826G>T p.G609V | Missense Mutation (SNP) | VAF 79/141 reads (56%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.844); catalogued as COSV61569557; called by muse, mutect2, varscan2
- NMRK1 | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 76/194 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1027865360, COSV63111643; called by muse, mutect2, varscan2
- NOD2 | c.538A>T p.R180W | Missense Mutation (SNP) | VAF 30/56 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV56048441; called by muse, mutect2, varscan2
- NPS | c.226G>C p.G76R | Missense Mutation (SNP) | VAF 65/284 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.582); catalogued as COSV67690486; called by muse, mutect2
- NPY1R | c.988G>C p.D330H | Missense Mutation (SNP) | VAF 82/109 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV56713356, COSV56713557; called by muse, mutect2, varscan2
- NRP2 | c.2270G>A p.G757E | Missense Mutation (SNP) | VAF 65/119 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55923663; called by muse, mutect2, varscan2
- OR10A7 | c.658C>T p.R220C | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.068); catalogued as rs138358769, COSV100406485; called by muse, mutect2, varscan2
- OR10J3 | c.540T>A p.C180* | Nonsense Mutation (SNP) | VAF 74/175 reads (42%) | catalogued as COSV59953646; called by muse, mutect2, varscan2
- OR14C36 | c.315del p.F105Lfs*28 | Frame Shift Del (DEL) | VAF 20/104 reads (19%) | catalogued as rs761899382; called by mutect2, varscan2
- OR1C1 | c.178T>A p.Y60N | Missense Mutation (SNP) | VAF 54/62 reads (87%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68715392; called by muse, mutect2, varscan2
- OR2T4 | c.436C>G p.L146V | Missense Mutation (SNP) | VAF 317/364 reads (87%) | SIFT deleterious (0); PolyPhen benign (0.417); catalogued as COSV63543380; called by muse, mutect2, varscan2
- OR2T8 | c.889G>A p.G297R | Missense Mutation (SNP) | VAF 250/292 reads (86%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.816); catalogued as rs1208698913, COSV60661569; called by muse, mutect2, varscan2
- OR56A4 | c.719C>T p.S240F | Missense Mutation (SNP) | VAF 16/109 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.132); catalogued as rs116778909, COSV58109297; called by muse, mutect2, varscan2
- OR5F1 | c.575C>A p.T192K | Missense Mutation (SNP) | VAF 32/111 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV53545327; called by muse, mutect2, varscan2
- OR6K2 | c.889G>T p.E297* | Nonsense Mutation (SNP) | VAF 63/160 reads (39%) | catalogued as COSV62743128; called by muse, mutect2, varscan2
- OTOP2 | c.745G>A p.E249K | Missense Mutation (SNP) | VAF 496/568 reads (87%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749488014, COSV58883538; called by muse, varscan2
- PAN2 | c.3608G>T p.*1203Lext*41 (on ENST00000425394 / NM_001127460.3; = p.*1199Lext*41 on NM_014871.5) | Nonstop Mutation (SNP) | VAF 16/30 reads (53%) | catalogued as COSV56263869; called by muse, mutect2, varscan2
- PAOX | c.1297A>C p.T433P | Missense Mutation (SNP) | VAF 64/119 reads (54%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.943); catalogued as COSV53371113; called by muse, mutect2, varscan2
- PAPPA2 | c.4343G>C p.C1448S | Missense Mutation (SNP) | VAF 146/172 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV62791209; called by muse, mutect2, varscan2
- PDE10A | c.936C>A p.D312E | Missense Mutation (SNP) | VAF 57/80 reads (71%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.992); catalogued as rs1360974603, COSV63091504, COSV63094741; called by muse, mutect2, varscan2
- PHF20L1 | c.23G>T p.R8L | Missense Mutation (SNP) | VAF 115/187 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV55188998, COSV55192890; called by muse, mutect2, varscan2
- PHTF1 | c.360G>T p.M120I | Missense Mutation (SNP) | VAF 50/91 reads (55%) | SIFT tolerated (0.4); PolyPhen benign (0.048); catalogued as COSV63366845; called by muse, mutect2, varscan2
- PIK3C2B | c.4834C>T p.R1612* | Nonsense Mutation (SNP) | VAF 70/74 reads (95%) | catalogued as rs373485341; called by muse, mutect2, varscan2
- PIK3CG | c.1085G>C p.R362T | Missense Mutation (SNP) | VAF 72/196 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV63245685; called by muse, mutect2, varscan2
- PJA1 | c.434A>T p.K145M | Missense Mutation (SNP) | VAF 22/28 reads (79%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.97); catalogued as COSV64052654; called by muse, mutect2, varscan2
- PLEKHG4 | c.272C>G p.S91* | Nonsense Mutation (SNP) | VAF 43/100 reads (43%) | catalogued as COSV64611816; called by muse, mutect2, varscan2
- PLEKHH2 | c.230C>G p.T77S | Missense Mutation (SNP) | VAF 37/98 reads (38%) | SIFT tolerated (0.34); PolyPhen benign (0.038); catalogued as COSV56749946; called by muse, mutect2, varscan2
- PLEKHM3 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 94/176 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.914); catalogued as COSV66815628; called by muse, mutect2, varscan2
- PLSCR5 | c.733G>A p.D245N | Missense Mutation (SNP) | VAF 145/397 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.819); catalogued as rs761966141, COSV71648929; called by muse, mutect2, varscan2
- PNLIPRP2 | c.321C>A p.D107E | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT tolerated (0.17); PolyPhen benign (0.023); catalogued as COSV53942272; called by muse, mutect2, varscan2
- PNLIPRP3 | c.548G>T p.G183V | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.752); catalogued as COSV65047114; called by muse, mutect2, varscan2
- POPDC2 | c.1015A>G p.R339G | Missense Mutation (SNP) | VAF 50/116 reads (43%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0); catalogued as COSV51739804; called by muse, mutect2, varscan2
- POU6F1 | c.1784G>A p.R595Q | Missense Mutation (SNP) | VAF 64/124 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.075); catalogued as rs1229420227, COSV61325911; called by muse, mutect2, varscan2
- PPP1R13L | c.731G>A p.R244Q | Missense Mutation (SNP) | VAF 39/105 reads (37%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.641); catalogued as rs767274852, COSV62907905; called by muse, mutect2, varscan2
- PRMT2 | c.479G>T p.R160L | Missense Mutation (SNP) | VAF 44/179 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.206); catalogued as COSV52454231, COSV52457620; called by muse, mutect2, varscan2
- PTPRB | c.4888A>G p.I1630V | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.114); catalogued as COSV54233015; called by muse, mutect2
- PTPRJ | c.641G>T p.R214L | Missense Mutation (SNP) | VAF 48/64 reads (75%) | SIFT tolerated (0.06); PolyPhen benign (0.062); catalogued as COSV69249930; called by muse, mutect2, varscan2
- PTX3 | c.859G>C p.G287R | Missense Mutation (SNP) | VAF 65/326 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.858); catalogued as COSV55821189; called by muse, mutect2, varscan2
- PUS10 | c.100C>G p.H34D | Missense Mutation (SNP) | VAF 27/96 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0.014); catalogued as COSV57450642; called by muse, mutect2, varscan2
- QRFPR | c.1027G>A p.V343I | Missense Mutation (SNP) | VAF 70/92 reads (76%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as COSV57675360; called by muse, mutect2, varscan2
- RDH13 | c.577A>G p.K193E (on ENST00000415061 / NM_001145971.2; = p.K122E on NM_138412.4) | Missense Mutation (SNP) | VAF 55/132 reads (42%) | SIFT tolerated (0.39); PolyPhen benign (0.039); catalogued as COSV52559669; called by muse, mutect2, varscan2
- RGL3 | c.1514C>A p.P505Q | Missense Mutation (SNP) | VAF 60/110 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748616435, COSV66506503; called by muse, mutect2, varscan2
- ROR1 | c.2240G>A p.R747Q | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.192); catalogued as rs1026892288, COSV64284126; called by muse, mutect2, varscan2
- RP1L1 | c.3151G>A p.V1051I | Missense Mutation (SNP) | VAF 27/40 reads (68%) | SIFT tolerated (0.11); PolyPhen benign (0.067); catalogued as COSV66751971; called by muse, mutect2, varscan2
- RPGRIP1L | c.663G>C p.Q221H | Missense Mutation (SNP) | VAF 96/212 reads (45%) | SIFT tolerated (0.22); PolyPhen benign (0.017); catalogued as COSV50902785; called by muse, mutect2, varscan2
- RPL19 | c.91G>A p.E31K | Missense Mutation (SNP) | VAF 39/264 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.098); catalogued as COSV56634854; called by muse, mutect2, varscan2
- RUFY3 | c.236G>T p.S79I | Missense Mutation (SNP) | VAF 222/1255 reads (18%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.999); catalogued as COSV56911426; called by muse, mutect2, varscan2
- RYR2 | c.12961G>A p.G4321S | Missense Mutation (SNP) | VAF 106/117 reads (91%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.642); catalogued as COSV63657690, COSV63663924; called by muse, mutect2, varscan2
- SALL1 | c.3529C>T p.L1177F | Missense Mutation (SNP) | VAF 31/92 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.526); catalogued as COSV51753577; called by muse, mutect2, varscan2
- SI | c.3491G>T p.G1164V | Missense Mutation (SNP) | VAF 63/329 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.8); catalogued as COSV52266839; called by muse, mutect2, varscan2
- SLC39A12 | c.533C>A p.S178Y | Missense Mutation (SNP) | VAF 39/127 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.878); catalogued as COSV66195342, COSV66201085; called by muse, mutect2, varscan2
- SLC39A12 | c.1295C>A p.A432D | Missense Mutation (SNP) | VAF 63/125 reads (50%) | SIFT tolerated (0.27); PolyPhen benign (0.123); catalogued as rs778543774, COSV66195357; called by muse, mutect2, varscan2
- SLC4A10 | c.2195T>A p.L732Q (on ENST00000446997 / NM_001354461.2; = p.L702Q on NM_022058.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 100/184 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55765460; called by muse, mutect2, varscan2
- SLC5A12 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 108/246 reads (44%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as COSV54819154, COSV99745675; called by muse, mutect2, varscan2
- SLCO4C1 | c.827T>C p.L276S | Missense Mutation (SNP) | VAF 90/162 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.672); catalogued as rs752601767, COSV60512942; called by muse, mutect2, varscan2
- SLITRK4 | c.1838G>T p.G613V | Missense Mutation (SNP) | VAF 98/112 reads (88%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.909); catalogued as COSV62022272; called by muse, mutect2, varscan2
- SLX4 | c.611G>A p.R204H | Missense Mutation (SNP) | VAF 195/396 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1410797507, COSV53561106; called by muse, mutect2, varscan2
- SOGA1 | c.1827C>A p.C609* | Nonsense Mutation (SNP) | VAF 8/23 reads (35%) | catalogued as COSV52912061; called by muse, mutect2, varscan2
- SOX5 | c.453G>A p.M151I | Missense Mutation (SNP) | VAF 40/140 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.155); catalogued as COSV100507195, COSV58619338; called by muse, mutect2, varscan2
- SPAG11B | c.281G>T p.R94I | Missense Mutation (SNP) | VAF 33/131 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as COSV52498836; called by muse, mutect2, varscan2
- SPATA31D1 | c.35C>A p.T12N | Missense Mutation (SNP) | VAF 96/240 reads (40%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.743); catalogued as COSV61192965; called by muse, mutect2, varscan2
- SPATA31D1 | c.1595T>A p.F532Y | Missense Mutation (SNP) | VAF 130/154 reads (84%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV61192982; called by muse, mutect2, varscan2
- SPHKAP | c.2380A>G p.K794E | Missense Mutation (SNP) | VAF 382/670 reads (57%) | SIFT tolerated (0.15); PolyPhen benign (0.044); catalogued as COSV60869227; called by muse, mutect2, varscan2
- SPTA1 | c.5526del p.V1843Sfs*9 | Frame Shift Del (DEL) | VAF 238/590 reads (40%) | catalogued as COSV63752779; called by mutect2, varscan2
- SPTA1 | c.1072C>A p.L358M | Missense Mutation (SNP) | VAF 292/574 reads (51%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.979); catalogued as COSV63749295; called by muse, mutect2, varscan2
- SRRM2 | c.1803G>T p.R601S | Missense Mutation (SNP) | VAF 45/116 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as COSV57068673; called by muse, mutect2, varscan2
- SSH2 | c.2524G>A p.E842K | Missense Mutation (SNP) | VAF 229/282 reads (81%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.318); catalogued as COSV52166902; called by muse, mutect2, varscan2
- SYMPK | c.226-2A>G p.X76_splice | Splice Site (SNP) | VAF 84/207 reads (41%) | catalogued as COSV55609755; called by muse, mutect2, varscan2
- TAF1 | c.668G>A p.R223H (on ENST00000373790 / NM_138923.4; = p.R244H on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.052); catalogued as rs765568995, COSV52107834; called by muse, mutect2, varscan2
- TAS2R40 | c.752A>G p.Y251C | Missense Mutation (SNP) | VAF 120/279 reads (43%) | SIFT tolerated (0.24); PolyPhen benign (0.05); catalogued as COSV68818111; called by muse, mutect2, varscan2
- TASP1 | c.851A>G p.Y284C | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.198); catalogued as rs1351927276, COSV61811490; called by muse, mutect2, varscan2
- TECPR1 | c.2045C>A p.A682D | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65782613; called by muse, mutect2, varscan2
- TEX55 | c.1016A>T p.H339L | Missense Mutation (SNP) | VAF 31/92 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV55210135, COSV55210325; called by muse, mutect2, varscan2
- TMEM106B | c.223G>A p.E75K | Missense Mutation (SNP) | VAF 41/111 reads (37%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.998); catalogued as COSV67543372; called by muse, mutect2, varscan2
- TMPRSS12 | c.416C>T p.T139I | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.038); catalogued as COSV68255806; called by muse, mutect2, varscan2
- TNF | c.361G>A p.D121N | Missense Mutation (SNP) | VAF 19/276 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.166); catalogued as rs1298153213, COSV69304184; called by muse, mutect2
- TNIK | c.1861G>A p.G621R | Missense Mutation (SNP) | VAF 56/455 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.05); catalogued as COSV52674271; called by muse, mutect2, varscan2
- TOP3A | c.234T>G p.Y78* | Nonsense Mutation (SNP) | VAF 18/35 reads (51%) | catalogued as COSV58175021; called by muse, mutect2, varscan2
- TRIT1 | c.349A>G p.I117V | Missense Mutation (SNP) | VAF 74/110 reads (67%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.557); catalogued as rs760669230, COSV57547148; called by muse, varscan2
- TTN | c.69823G>C p.V23275L (on ENST00000591111; = p.V15851L on NM_003319.4) | Missense Mutation (SNP) | VAF 54/205 reads (26%) | PolyPhen benign (0); catalogued as COSV59899738; called by muse, mutect2, varscan2
- TTN | c.8702T>A p.F2901Y (on ENST00000591111; = p.F2855Y on NM_003319.4) | Missense Mutation (SNP) | VAF 65/228 reads (29%) | PolyPhen probably damaging (0.915); catalogued as COSV59899765; called by muse, mutect2, varscan2
- TTYH1 | c.776G>A p.G259D | Missense Mutation (SNP) | VAF 76/182 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.272); catalogued as COSV56609779; called by muse, mutect2, varscan2
- UBQLNL | c.1141C>A p.P381T | Missense Mutation (SNP) | VAF 105/227 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.466); catalogued as COSV66492668; called by muse, mutect2, varscan2
- UGT2B10 | c.1574G>T p.G525V | Missense Mutation (SNP) | VAF 34/343 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as COSV55318779, COSV55318917; called by muse, varscan2
- UPF2 | c.1618G>A p.A540T | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as COSV62658488; called by muse, mutect2, varscan2
- UQCRC2 | c.908G>A p.S303N | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV51670818, COSV51672257; called by muse, mutect2, varscan2
- USH2A | c.4662A>T p.E1554D | Missense Mutation (SNP) | VAF 106/136 reads (78%) | SIFT tolerated (0.95); PolyPhen benign (0.018); catalogued as COSV56330738; called by muse, mutect2, varscan2
- USP37 | c.1642G>T p.V548F | Missense Mutation (SNP) | VAF 80/130 reads (62%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV51441462, COSV51446779; called by muse, mutect2, varscan2
- VAV1 | c.1624C>G p.Q542E | Missense Mutation (SNP) | VAF 127/226 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); catalogued as COSV58379005; called by muse, mutect2, varscan2
- VCPIP1 | c.62C>T p.P21L | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.098); catalogued as rs781413886, COSV60046083; called by muse, mutect2, varscan2
- WDR36 | c.1449C>G p.Y483* | Nonsense Mutation (SNP) | VAF 53/91 reads (58%) | catalogued as COSV72411039; called by muse, mutect2, varscan2
- ZBTB45 | c.671A>T p.E224V | Missense Mutation (SNP) | VAF 148/650 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.203); catalogued as COSV54018083; called by muse, mutect2, varscan2
- ZCCHC7 | c.492G>C p.E164D | Missense Mutation (SNP) | VAF 141/187 reads (75%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as COSV100383483, COSV59718577; called by muse, mutect2, varscan2
- ZEB1 | c.2203C>T p.L735F | Missense Mutation (SNP) | VAF 37/138 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58036900; called by muse, mutect2, varscan2
- ZFHX4 | c.863G>T p.G288V | Missense Mutation (SNP) | VAF 76/145 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760824197, COSV50508042; called by muse, mutect2, varscan2
- ZFP14 | c.1354T>C p.Y452H | Missense Mutation (SNP) | VAF 45/247 reads (18%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as COSV54201078; called by muse, mutect2, varscan2
- ZFP90 | c.211G>C p.E71Q | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.462); catalogued as COSV68050633; called by muse, mutect2, varscan2
- ZNF30 | c.170G>T p.R57L | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV57852658; called by muse, mutect2, varscan2
- ZNF423 | c.2322G>C p.Q774H (on ENST00000563137 / NM_001379286.1; = p.Q766H on NM_015069.4) | Missense Mutation (SNP) | VAF 44/96 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.322); catalogued as COSV52178269; called by muse, mutect2, varscan2
- ZNF423 | c.712G>T p.G238C (on ENST00000563137 / NM_001379286.1; = p.G230C on NM_015069.4) | Missense Mutation (SNP) | VAF 53/139 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV52178288; called by muse, mutect2, varscan2
- ZNF44 | c.1304A>T p.H435L (on ENST00000356109 / NM_001164276.2; = p.H387L on NM_016264.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 59/107 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61134726; called by muse, mutect2, varscan2
- ZNF536 | c.460G>C p.G154R | Missense Mutation (SNP) | VAF 33/91 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV62818959; called by muse, mutect2, varscan2
- ZNF548 | c.529G>T p.E177* | Nonsense Mutation (SNP) | VAF 40/103 reads (39%) | catalogued as COSV60240345; called by muse, mutect2, varscan2
- ZNF607 | c.1687T>C p.C563R | Missense Mutation (SNP) | VAF 62/121 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs146672126, COSV67696199; called by muse, mutect2, varscan2
- ZNF835 | c.950A>G p.Q317R | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.3); PolyPhen benign (0.423); catalogued as rs749435198, COSV73379197; called by muse, mutect2, varscan2
- ZSCAN1 | c.317G>T p.C106F | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.972); catalogued as rs370395921; called by muse, mutect2, varscan2
- AVIL | c.2273_2274del p.Y758Lfs*16 | Frame Shift Del (DEL) | VAF 74/314 reads (24%) | called by pindel, varscan2
- GDF2 | c.797A>G p.K266R | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT tolerated (0.32); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- KCNT2 | c.3173del p.N1058Ifs*3 | Frame Shift Del (DEL) | VAF 159/240 reads (66%) | called by mutect2, pindel, varscan2
- MECOM | c.1440dup p.A481Cfs*2 (on ENST00000468789 / NM_001105078.4; = p.A669Cfs*2 on NM_004991.4) | Frame Shift Ins (INS) | VAF 186/638 reads (29%) | called by mutect2, pindel, varscan2
- OR8B8 | c.698del p.G233Afs*13 | Frame Shift Del (DEL) | VAF 93/151 reads (62%) | called by mutect2, pindel, varscan2
- SLITRK2 | c.570del p.N191Ifs*3 | Frame Shift Del (DEL) | VAF 35/163 reads (21%) | called by mutect2, pindel, varscan2
- SNTG2 | c.804del p.W268Cfs*12 | Frame Shift Del (DEL) | VAF 8/9 reads (89%) | called by mutect2, varscan2
- SPATA31A1 | c.392C>G p.P131R | Missense Mutation (SNP) | VAF 111/150 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- SPTBN2 | c.5122_5131del p.Q1708Rfs*19 | Frame Shift Del (DEL) | VAF 29/111 reads (26%) | called by mutect2, pindel, varscan2
- TTN | c.731_739del p.A244_Q247delinsE | In Frame Del (DEL) | VAF 44/86 reads (51%) | called by mutect2, pindel*, varscan2
- ABCA2 | c.2229G>A p.V743= (on ENST00000614293; = p.V713= on NM_001606.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 48/50 reads (96%) | catalogued as COSV55797801; called by muse, varscan2
- AMACR | c.450G>T p.L150= | Silent (SNP) | VAF 33/125 reads (26%) | catalogued as COSV59459774; called by muse, mutect2, varscan2
- ANO4 | c.303G>A p.V101= (on ENST00000392977 / NM_001286615.2; = p.V66= on NM_178826.4) | Silent (SNP) | VAF 82/144 reads (57%) | catalogued as rs775343966, COSV54586298; called by muse, mutect2, varscan2
- ATP2B2 | c.2145G>T p.T715= (on ENST00000352432; = p.T681= on NM_001683.5) | Silent (SNP) | VAF 48/66 reads (73%) | catalogued as rs768888914, COSV59489907, COSV59495553; called by muse, mutect2, varscan2
- BCL2L2 | c.276C>T p.N92= | Silent (SNP) | VAF 67/196 reads (34%) | catalogued as COSV51635488; called by muse, mutect2, varscan2
- BNIP2 | c.147G>A p.V49= | Silent (SNP) | VAF 12/43 reads (28%) | catalogued as COSV51105123; called by muse, mutect2
- CATSPER1 | c.2160G>A p.L720= | Silent (SNP) | VAF 46/126 reads (37%) | catalogued as COSV56409072; called by muse, mutect2, varscan2
- CDK12 | c.1455G>A p.E485= | Silent (SNP) | VAF 323/548 reads (59%) | catalogued as COSV70999386; called by muse, mutect2, varscan2
- CNGA4 | c.324C>T p.R108= | Silent (SNP) | VAF 148/304 reads (49%) | catalogued as rs1291444342, COSV66005130; called by muse, varscan2
- CNTNAP2 | c.2403C>A p.A801= | Silent (SNP) | VAF 98/224 reads (44%) | catalogued as COSV62147863; called by muse, mutect2, varscan2
- CORIN | c.1524C>T p.F508= | Silent (SNP) | VAF 54/147 reads (37%) | catalogued as COSV56686640; called by muse, mutect2, varscan2
- CTNND2 | c.1923G>C p.L641= | Silent (SNP) | VAF 102/202 reads (50%) | catalogued as COSV58866972; called by muse, mutect2, varscan2
- DLGAP3 | c.1965C>T p.F655= | Silent (SNP) | VAF 43/83 reads (52%) | catalogued as COSV52391623; called by muse, mutect2, varscan2
- DOCK5 | c.873G>T p.R291= | Silent (SNP) | VAF 5/37 reads (14%) | called by muse, mutect2
- EPB41L3 | c.976C>A p.R326= | Silent (SNP) | VAF 150/318 reads (47%) | catalogued as COSV59445208, COSV59460193; called by muse, mutect2, varscan2
- GAA | c.1746C>T p.A582= | Silent (SNP) | VAF 93/113 reads (82%) | catalogued as COSV56406976; called by muse, mutect2, varscan2
- GRIN2B | c.2526C>T p.F842= | Silent (SNP) | VAF 86/141 reads (61%) | catalogued as rs867624672, COSV74204847; called by muse, mutect2, varscan2
- HELT | c.51G>C p.V17= | Silent (SNP) | VAF 12/14 reads (86%) | catalogued as COSV58819624; called by muse, mutect2, varscan2
- IGHG1 | c.591G>A p.L197= | Silent (SNP) | VAF 238/581 reads (41%) | called by muse, mutect2, varscan2
- ITGB2 | c.22C>T p.L8= | Silent (SNP) | VAF 15/22 reads (68%) | catalogued as COSV56607872; called by muse, mutect2, varscan2
- ITSN1 | c.996A>G p.E332= | Silent (SNP) | VAF 24/93 reads (26%) | catalogued as COSV66080895; called by muse, mutect2, varscan2
- KATNIP | c.3687T>G p.T1229= | Silent (SNP) | VAF 59/130 reads (45%) | catalogued as rs1386193170, COSV55173963; called by muse, mutect2, varscan2
- KCNK3 | c.418C>T p.L140= | Silent (SNP) | VAF 116/138 reads (84%) | catalogued as rs755486166, COSV57191559; called by muse, mutect2, varscan2
- KCTD9 | c.24G>A p.L8= | Silent (SNP) | VAF 8/49 reads (16%) | catalogued as COSV55339287; called by muse, mutect2
- LRGUK | c.951G>A p.L317= | Silent (SNP) | VAF 69/171 reads (40%) | catalogued as COSV53634282; called by muse, mutect2, varscan2
- LRRC2 | c.798C>G p.L266= | Silent (SNP) | VAF 43/58 reads (74%) | catalogued as rs968173384, COSV56124990; called by muse, mutect2, varscan2
- LRRC7 | c.696T>C p.N232= (on ENST00000651989 / NM_001370785.2; = p.N199= on NM_001330635.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 13/67 reads (19%) | catalogued as rs1387378558, COSV50413331; called by muse, mutect2, varscan2
- MAPKAPK2 | c.507C>T p.S169= | Silent (SNP) | VAF 268/327 reads (82%) | catalogued as COSV54314456; called by muse, mutect2, varscan2
- MAS1L | c.621A>G p.V207= | Silent (SNP) | VAF 106/118 reads (90%) | catalogued as COSV65808502; called by muse, mutect2, varscan2
- MASP1 | c.1989G>A p.V663= | Silent (SNP) | VAF 61/244 reads (25%) | catalogued as rs1248826715, COSV61824321; called by muse, mutect2, varscan2
- MDGA2 | c.2283G>A p.G761= (on ENST00000399232 / NM_001113498.2; = p.G463= on NM_182830.4) | Silent (SNP) | VAF 26/83 reads (31%) | catalogued as rs759454328, COSV62079914; called by muse, mutect2, varscan2
- MROH5 | c.597C>T p.H199= | Silent (SNP) | VAF 28/42 reads (67%) | catalogued as COSV71300524; called by muse, mutect2, varscan2
- MUC16 | c.1974G>T p.T658= | Silent (SNP) | VAF 106/224 reads (47%) | catalogued as rs772586153, COSV101200366, COSV67446611; called by muse, mutect2, varscan2
- NUTM1 | c.3223C>A p.R1075= | Silent (SNP) | VAF 24/88 reads (27%) | catalogued as COSV59215827, COSV59218697; called by muse, varscan2
- OPN5 | c.861C>A p.L287= | Silent (SNP) | VAF 338/387 reads (87%) | catalogued as COSV55244287; called by muse, mutect2, varscan2
- OR2M2 | c.876C>T p.L292= | Silent (SNP) | VAF 83/342 reads (24%) | catalogued as COSV62897844; called by muse, mutect2, varscan2
- OR7G3 | c.675C>T p.V225= | Silent (SNP) | VAF 41/142 reads (29%) | catalogued as COSV59639902; called by muse, mutect2, varscan2
- PCDH11X | c.87C>A p.T29= | Silent (SNP) | VAF 86/97 reads (89%) | catalogued as COSV53444581; called by muse, mutect2, varscan2
- PCLO | c.10341G>T p.T3447= | Silent (SNP) | VAF 62/158 reads (39%) | catalogued as COSV61615170, COSV61629759; called by muse, mutect2, varscan2
- PKD1 | c.1353C>T p.A451= | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as rs758484008, COSV51911120; called by muse, varscan2
- PKHD1L1 | c.2997A>T p.L999= | Silent (SNP) | VAF 32/56 reads (57%) | catalogued as COSV65737613, COSV65745656; called by muse, mutect2, varscan2
- PKHD1L1 | c.12417T>C p.S4139= | Silent (SNP) | VAF 40/165 reads (24%) | catalogued as COSV65737621; called by muse, mutect2, varscan2
- PLAG1 | c.1005G>A p.P335= | Silent (SNP) | VAF 143/244 reads (59%) | catalogued as rs150353769; called by muse, mutect2, varscan2
- PLXNA4 | c.3732G>T p.V1244= | Silent (SNP) | VAF 20/41 reads (49%) | called by muse, mutect2
- PPP6R1 | c.2328C>T p.P776= | Silent (SNP) | VAF 21/24 reads (88%) | catalogued as COSV58983731; called by muse, mutect2, varscan2
- RNASE3 | c.163C>A p.R55= | Silent (SNP) | VAF 103/217 reads (47%) | catalogued as rs115812876, COSV58959154; called by muse, mutect2, varscan2
- SCARB1 | c.819G>A p.E273= | Silent (SNP) | VAF 9/53 reads (17%) | catalogued as COSV55544282; called by muse, mutect2, varscan2
- SFMBT2 | c.1917G>A p.L639= | Silent (SNP) | VAF 148/282 reads (52%) | catalogued as COSV62805629; called by muse, mutect2, varscan2
- SLC16A2 | c.462C>A p.I154= | Silent (SNP) | VAF 115/130 reads (88%) | catalogued as COSV52082703; called by muse, mutect2, varscan2
- SLC26A4 | c.2292G>T p.T764= | Silent (SNP) | VAF 58/138 reads (42%) | catalogued as COSV55914548; called by muse, mutect2, varscan2
- SLITRK1 | c.546C>G p.L182= | Silent (SNP) | VAF 79/108 reads (73%) | catalogued as COSV65674380, COSV65677407; called by muse, mutect2, varscan2
- SPPL2B | c.339C>A p.R113= | Silent (SNP) | VAF 41/70 reads (59%) | catalogued as COSV66316756, COSV66316920, COSV66317183; called by muse, mutect2, varscan2
- SRD5A1 | c.360G>A p.A120= | Silent (SNP) | VAF 98/178 reads (55%) | catalogued as rs142854865; ClinVar: likely benign; called by muse, mutect2, varscan2
- TLK1 | c.1648C>T p.L550= | Silent (SNP) | VAF 94/175 reads (54%) | catalogued as rs756285074, COSV62629033; called by muse, mutect2, varscan2
- TLN2 | c.354T>C p.C118= | Silent (SNP) | VAF 81/185 reads (44%) | catalogued as COSV60885845; called by muse, mutect2, varscan2
- TMPRSS4 | c.531G>A p.R177= | Silent (SNP) | VAF 29/35 reads (83%) | catalogued as rs1565434490, COSV71108382; called by muse, mutect2, varscan2
- TSLP | c.21A>G p.L7= | Silent (SNP) | VAF 134/219 reads (61%) | catalogued as rs149732987; called by muse, mutect2, varscan2
- TTC3 | c.63T>A p.P21= | Silent (SNP) | VAF 249/433 reads (58%) | catalogued as COSV61286139; called by muse, mutect2, varscan2
- UBC | c.438G>T p.V146= | Silent (SNP) | VAF 234/441 reads (53%) | catalogued as COSV60058285; called by muse, mutect2, varscan2
- XIRP2 | c.274C>A p.R92= | Silent (SNP) | VAF 36/66 reads (55%) | catalogued as COSV54683865, COSV54731845; called by muse, mutect2, varscan2
- ZHX2 | c.978G>A p.V326= | Silent (SNP) | VAF 42/195 reads (22%) | catalogued as COSV58710429; called by muse, mutect2, varscan2
- ZNF250 | c.408G>A p.K136= | Silent (SNP) | VAF 65/366 reads (18%) | catalogued as rs1041468465, COSV52968011; called by muse, mutect2, varscan2
- ZNF285 | c.477C>A p.P159= | Silent (SNP) | VAF 109/289 reads (38%) | catalogued as COSV58408063; called by muse, mutect2, varscan2
- ZNF536 | c.3846T>A p.L1282= | Silent (SNP) | VAF 69/178 reads (39%) | catalogued as COSV62818967; called by muse, mutect2, varscan2
- ZNF559 | c.1614G>T p.V538= | Silent (SNP) | VAF 49/150 reads (33%) | catalogued as COSV57835014; called by muse, mutect2, varscan2
- ZSWIM5 | c.2143T>C p.L715= | Silent (SNP) | VAF 66/118 reads (56%) | catalogued as COSV62732643; called by muse, mutect2, varscan2
- CNTN3 | c.-1G>A | 5'UTR (SNP) | VAF 24/31 reads (77%) | catalogued as COSV55163752, COSV99723628; called by muse, mutect2, varscan2
- COL6A2 | c.2462-2501A>T | Intron (SNP) | VAF 15/35 reads (43%) | catalogued as COSV100153060; called by muse, mutect2, varscan2
- EI24P4 | n.888C>G | RNA (SNP) | VAF 214/540 reads (40%) | called by muse, mutect2, varscan2
- OTUD6B | chr8:91070339 C>G | 5'Flank (SNP) | VAF 6/31 reads (19%) | catalogued as COSV53442038; called by muse, mutect2, varscan2
- RMDN2 | c.452+21952C>G | Intron (SNP) | VAF 113/128 reads (88%) | catalogued as COSV99307354; called by muse, mutect2, varscan2
- SNORD115-20 | n.80C>T | RNA (SNP) | VAF 150/322 reads (47%) | called by muse, mutect2, varscan2
